CPTAC case 20BR007 — Breast — Ductal and Lobular Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/1eef079e-d5cd-4a0c-a9b5-525865aa7847

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 53.9 years (19,679 days); AJCC pathologic stage: Stage IIA; Prior malignancy: no.

Biospecimens (2 samples)
- Sample 547f521a-5851-426c-a125-d9d82c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 58f39d9c-9c17-4268-a206-564f83: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
